TCGA case TCGA-CD-A486 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: ILSBio. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c63ae423-c90a-4cf4-aa42-653bb8fa3e69

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 68 years; Vital status: Dead; Days to death: 192 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 68.1 years (24,879 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 192 days.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Cisplatin + Paclitaxel; Days to treatment start: 37 days; Days to treatment end: 57 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Liver. Age at diagnosis: 68.3 years (24,958 days); Days to diagnosis: 79 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Days to follow up: 2 days; Disease response: Tumor Free.
- Day 79 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 79 days.
- Days to follow up: 104 days; Disease response: Tumor Free.
- Days to follow up: 192 days; Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CD-A486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 490 mg.
  Slide TCGA-CD-A486-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CD-A486-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CD-A486-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Cardia/Proximal; Lymph nodes examined: No; History reflux disease indicator: No; Antireflux treatment: No; Number of relatives with stomach cancer: 0; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; New tumor event site other: liver and lung; Treatment outcome first course: Complete Remission/Response; Cause of death: Stomach Cancer.
- Follow-up form 2, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 192 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 192 days; disease-free interval: event (new tumor event after initially disease-free), 79 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 79 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CD-A486-01A-11D-A24C-01): tumor purity 0.57, ploidy 3.98, whole-genome doublings 1.
